Somatic mutation profile of tumor specimen BA2301D (aliquot aq-BA2301D) from BEATAML1.0 case 2197, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 42.5 years (15,535 days).
Specimen BA2301D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 93ed629d-070a-42b5-a22f-826defa0639c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2320D (Solid Tissue Normal), aliquot aq-BA2320D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7250b41e-852b-457d-b195-af583bcf8835

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 5, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 28/342 reads (8%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- PCDHA7 | c.1092A>T p.Q364H | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.025); catalogued as rs141258579; called by muse, mutect2
- GOT1 | c.798G>C p.E266D | Missense Mutation (SNP) | VAF 42/92 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.555); called by muse, mutect2, varscan2
- KRT40 | c.541G>T p.E181* | Nonsense Mutation (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2
- MYH13 | c.4990G>T p.A1664S | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.46); PolyPhen benign (0.058); called by muse, mutect2
- PARP3 | c.1126C>A p.L376M | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.827); called by muse, mutect2
- KCNH4 | c.2703G>T p.L901= | Silent (SNP) | VAF 5/25 reads (20%) | called by muse, mutect2
